CGCI case BLGSP-71-23-00405 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/547cbd11-21d9-4d81-b643-d376e081bd3f

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 60 years; Vital status: Dead; Days to death: 250 days.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 60.2 years (21,987 days); Year of diagnosis: 2014; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 241 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Axillary lymph nodes; Sites of involvement: Liver / Stomach / Kidney, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Tumor largest dimension diameter: 3 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 241 days; Disease response: With Tumor.
- Follow-up contacts recording only the day: day 0, day 7.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Negative; Specialized molecular test: Ki-67 > 90%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC (IHC): Positive.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 1878 [Blood test normal range upper: 480].

Other clinical attributes
- Day 0: Weight: 60 kg; Height: 160 cm; BMI: 23.4; CD4 count: 57; Haart treatment indicator: No; HIV viral load: 355000.
- Day 7: Comorbidities: HIV/AIDS.
- Day 7: Risk factors: HIV/AIDS.
- Day 241: Nadir CD4 count: 286.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00405-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00405-01A-01-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-23-00405-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 5; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 25; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00405-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-23-00405-01-HE-1: Tissue microarray coordinates: B1,C4,A5.
  Slide BLGSP-71-23-00405-01-Ki67: Tissue microarray coordinates: B1,C4,A5.
  Slide BLGSP-71-23-00405-01-CD3: Tissue microarray coordinates: B1,C4,A5.
  Slide BLGSP-71-23-00405-01-BCL6: Tissue microarray coordinates: B1,C4,A5.
  Slide BLGSP-71-23-00405-01-BCL2: Tissue microarray coordinates: B1,C4,A5.
  Slide BLGSP-71-23-00405-01-CD10: Tissue microarray coordinates: B1,C4,A5.
  Slide BLGSP-71-23-00405-01-CD20: Tissue microarray coordinates: B1,C4,A5.
- Sample BLGSP-71-23-00405-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00405-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 70; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 10.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Days to HIV diagnosis: 7; Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: No.
- Primary pathology: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); Extranodal site involvement: 4; Days from index date to tumor sample procurement: -18.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 1878; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: C-myc.
